TCGA case TCGA-BP-4352 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/037c691e-6320-451b-9276-78459f1b705c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 344 days.

Diagnoses (4)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 74.6 years (27,253 days); Year of diagnosis: 2007; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 10.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Treatment intent type: Palliative; Days to treatment start: 35 days; Days to treatment end: 59 days; Route of administration: Oral.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Palliative; Days to treatment start: 61 days; Days to treatment end: 74 days; Treatment dose: 3,000 cGy; Course number: 1; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Palliative; Days to treatment start: 263 days; Days to treatment end: 270 days; Treatment dose: 3,000 cGy; Course number: 2; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Palliative; Days to treatment start: 271 days; Days to treatment end: 277 days; Treatment dose: 3,000 cGy; Course number: 3; Number of fractions: 5; Treatment anatomic sites: Distant Site.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 74.7 years (27,266 days); Days to diagnosis: 13 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 75.3 years (27,496 days); Days to diagnosis: 243 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.
4. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 75.3 years (27,518 days); Days to diagnosis: 265 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 277 days; Treatment anatomic sites: Distant Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Day 13 (post initial treatment): Progression or recurrence: Yes.
- Day 243 (post initial treatment): Progression or recurrence: Yes.
- Day 265 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 265 days.
- Days to follow up: 344 days; Disease response: With Tumor.

Molecular and laboratory tests
- Leukocytes: Elevated.
- Platelets: Normal.
- Hemoglobin: Low.
- Calcium: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-4352-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.6; Intermediate dimension: 1.5; Shortest dimension: 0.4.
  Slide TCGA-BP-4352-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-BP-4352-01A-01-BS1: Section location: Bottom; Percent tumor cells: 84; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 15.
- Sample TCGA-BP-4352-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-4352-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.4; Intermediate dimension: 1.7; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: PO.
- Radiation treatment 1: Radiation type other: Not specified.
- Radiation treatment 2: Radiation type other: not specified.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form 2: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: Yes.
- Follow-up form 3: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 344 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 344 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 13 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-BP-4352-01): tumor purity 0.68, ploidy 3.67, whole-genome doublings 2 (call status: legacy_call).
